Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A0Z9, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A0Z9-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid cancer.

PROCEDURE: Thyroidectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

100-0-3

carcinoma, papillary, tall cell variant 8344/3

Site: thyroid, NOS C73.9 hx 11/27/11

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (11.6 GRAMS) -

A. PAPILLARY THYROID CARCINOMA, TWO FOCI:

i. TALL CELL VARIANT WITH FOCAL SQUAMOUS METAPLASIA (2.8 CM), LEFT LOBE, WITH EXTRATHYROIDAL EXTENSION TO MARGIN; PERINEURAL AND ANGIOLYMPHATIC INVASION PRESENT (see comment).

ii. MICROCARCINOMA (0.1 CM), RIGHT LOBE, CONFINED TO THYROID; NO ANGIOLYMPHATIC INVASION.

B. PATHOLOGIC STAGE: pT3 N0.

C. SLIGHT NODULAR HYPERPLASIA

PART 2: LYMPH NODE, CENTRAL COMPARTMENT, BIOPSY -

A. SIX LYMPH NODES, NO TUMOR PRESENT (0/6).

B. FRAGMENT OF NORMOCYLLULAR PARATHYROID GLAND, NO TUMOR PRESENT.

COMMENT:

This tumor also has some foci of with (sic) 'hobnail' features. This histology has been recently proposed as yet another aggressive variant of papillary thyroid carcinoma (see reference).

REFERENCE:

Papillary thyroid carcinoma with prominent hobnail features: a new aggressive variant of moderately differentiated papillary carcinoma. A clinicopathologic, immunohistochemical, and molecular study of eight cases.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE:

Total Thyroidectomy

TUMOR SITE:

Right Lobe, Left Lobe ✓

TUMOR FOCALITY:

Multifocal ✓

TUMOR SIZE (largest nodule):

Greatest Dimension: 2.8 cm

HISTOLOGIC TYPE:

Papillary carcinoma, tall cell variant ✓

PATHOLOGIC STAGING (pTNM):

pT3

pN0

Number of regional lymph nodes examined: 6

Number of regional lymph nodes involved: 0

pMX

MARGINS:

Margin(s) involved by carcinoma

Site(s) of involvement: LEFT

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Other: focal squamous metaplasia and hobnail features

Source: NCI Genomic Data Commons file 428f24ee-1fa2-4f9d-8315-61b2435e4eb2 (TCGA-BJ-A0Z9.978BAD0D-EC7B-4E7A-AB18-8507DDAF1266.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).